Surgical pathology report (de-identified scan), TCGA case TCGA-FB-AAQ1, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-AAQ1-01A (Primary Tumor).

[page 1 of 4]
TSS Patient ID:

Surgical Date:

Gross Description: Whipple (long black stitch = pancreatic duct margin, blue stitch = portal vein margin, looped blue = SMA, looped black = deep radial margin):

The specimen consists of a portion of duodenum measuring 22 cm in length x 4 cm in outer diameter with adhered pancreatic tissue measuring 12 x 8 x 5 cm. The pancreatic tissue has a portal vein vascular groove measuring 10 cm in length which is designated by the long single blue stitch. The proximal duodenal staple line measures 6 cm in length, with adhered pancreatic tissue within 0.5 cm of the surgical staple line and adhered pancreatic tissue extending down the length of the pancreatic duodenal junction. The distal staple line measures 5 cm in length. The pancreatic duct margin is marked with a long black stitch and is shaved en face for frozen section (E1). Additionally there is a looped blue surgical stitch designating the SMA margin and a looped black stitch designating the deep radial margin. The main pancreatic duct measures 0.5 cm in diameter, and is hemorrhagic in appearance. After the sample is taken for frozen section, the residual pancreatic neck margin is inked orange, the vascular groove is inked blue, and the remaining radial margin is inked black. The common bile duct diameter measures 0.7 cm and a metal surgical stent is in place extending down through the ampulla into the duodenum. The cystic duct is identified and is probe patent to the common bile duct. The distal duodenal margin is inked black as well as the proximal duodenal margin which are shaved, and the duodenum is opened longitudinally to reveal a dusky tan-brown mucosal surface with normal appearing folds. There is a

ICD-O-3
Adenocarcinoma, duodenum NOS 8000/3
Site: pancreas head 025.0
Q12 5/16/14

[page 2 of 4]
small segment of pylorus at the proximal margin measuring 1 cm in length.

Additionally there is a small polyp measuring 0.8 x 0.4 x 0.4 cm,

approximately 1 cm away from the distal margin. Additionally approximately

2 cm from the ampulla there is a small 0.3 x 0.3 cm polyp.

The pancreas is serially sectioned to reveal a 6 x 6 x 3 cm lesion with a

tan-white-to-yellow cut surface with several areas of possible necrosis.

The lesion extends up to but not through both the vascular groove margin

and the deep radial margin and comes to within 0.3 cm of the new pancreatic

neck margin. Additionally the lesion appears to be grossly encompassing

the main pancreatic duct as well as the common bile duct. There is a small

amount of residual lobular tan-yellow pancreatic tissue nearest to the

proximal duodenal margin. No other abnormalities or satellite lesions are

identified.

There is a small amount of peripancreatic adipose tissue, which is palpated

for lymph nodes and all possible lymph nodes are submitted

Microscopic Description:

Diagnosis Details: Pancreatic adenocarcinoma of pancreatic head, moderately differentiated

- 6 cm in greatest dimension

- New neck and vascular groove margin negative for malignancy

- Tumor focally extends to deep margin (slide E4)

- Tumor directly extends into ampulla and duodenal muscularis (slide E11)

- Angiolymphatic and perineural invasion identified

- Metastatic pancreatic carcinoma present in three of twenty lymph nodes with extra capsular extension (3/20)

- AJCC pathologic stage (7th Edition): pT3 N1

Pancreas (Exocrine) Cancer Synopsis Specimens Involved Specimens:

[page 3 of 4]
E: Whipple FS

Specimen: Head of pancreas

Procedure: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

Tumor Site: Pancreatic head

Tumor size greatest dimension: 6cm

Histologic Type: Ductal adenocarcinoma

Histologic Grade (ductal carcinoma only): G2

Microscopic Tumor Extension: Tumor invades ampulla of Vater or sphincter of Oddi, Tumor invades duodenal wall

AJCC Stage (7th Edition) (pTNM)

Primary Tumor (pT): pT3

Regional Lymph Nodes (pN): pN1 Number of regional lymph nodes involved: 3 Number of regional lymph nodes examined: 27

Distant Metastasis (pM): Not applicable

Pancreatic neck margin: Negative

Portal vein margin: Negative

Superior mesenteric artery margin: Negative

Deep radial margin: Positive

Duodenom/gastric margin: Negative

Jejunal margin: Negative

Treatment Effect: No prior treatment

Angiolymphatic Invasion: Present

Perineural Invasion: Present

Additional Pathologic Findings: Chronic pancreatitis

Comments:

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

[page 4 of 4]
Specimen type: Whipple resection

Tumor site: Head

Tumor size: 6 cm

Histologic type: Adenocarcinoma, ductal type

Histologic grade: Moderately differentiated

Tumor extent: Other - Small intestine, ampulla of Vater

Lymph nodes: 3/27 positive for metastasis (Regional 3/27)

Lymphatic invasion: Present

Venous invasion: Present

Margins: Involved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 4cc0d8aa-73d8-46aa-a4a5-028bf958b095 (TCGA-FB-AAQ1.7909A98D-8096-46D7-9CE8-94E258BDEF2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).